Gene-level copy-number profile of tumor specimen TCGA-NF-A4WU-01A from TCGA case TCGA-NF-A4WU, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 60.0 years (21,901 days).
Specimen TCGA-NF-A4WU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.8a09e36c-bff4-4eee-a9c1-0bd45ec8c3a9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NF-A4WU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6ecf6a19-7267-40e8-934b-fd7c8f3d9a4b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,658; copy number 2: 40,467; copy number 3: 6,630; copy number 4: 2,025; copy number 5: 20; copy number 6: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NF-A4WU-01A-11D-A28Q-01): tumor purity 0.55, ploidy 3.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 40 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:225,486,835–226,090,465, 20 genes, copy number 5 (within-gene range 2–5): ENAH, AC099066.2, AC099066.1, RNU6-1304P, SRP9, AC099066.3, EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2, AL512343.2, H3-3A, LINC01703.
- chr12:21,264,600–22,065,674, 18 genes, copy number 6 (within-gene range 4–6): SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS.
- chr12:22,104,491–22,134,851, 2 genes, copy number 6 (within-gene range 4–6): AC007671.1, SULT6B2P.

Autosomal genes at a single copy (total copy number 1): 10,658. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
